Somatic mutation profile of tumor specimen TARGET-10-PAPHLH-09A (aliquot TARGET-10-PAPHLH-09A-01D) from TARGET case TARGET-10-PAPHLH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,666 days).
Specimen TARGET-10-PAPHLH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ae277ae-0223-4830-bc04-49ea9ab74ce3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHLH-10A (Blood Derived Normal), aliquot TARGET-10-PAPHLH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63ab3151-a255-45f1-9cf7-86389077884a

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSP | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs749051278, COSV65792211; ClinVar: uncertain significance; called by muse, mutect2
- FAT4 | c.14008G>A p.G4670R | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV58679330; called by muse, mutect2
- IL7R | c.727_728insCCTGCC p.L242_L243insPC | In Frame Ins (INS) | VAF 32/96 reads (33%) | catalogued as COSV57405510, COSV57408205, COSV57408696, COSV57410138, COSV57410369, COSV57415525, COSV99073416; called by mutect2, pindel, varscan2
- NES | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763081922, COSV63961383; called by muse, mutect2, varscan2
- NF1 | c.6819G>A p.K2273= (on ENST00000358273 / NM_001042492.3; = p.K2252= on NM_000267.3) | Splice Region (SNP) | VAF 54/125 reads (43%) | catalogued as rs1060500373, COSV62193968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FABP7 | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KRTAP10-2 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- TRDV2 | chr14:22423040 ins CC | Frame Shift Ins (INS) | VAF 18/30 reads (60%) | called by pindel, varscan2
- MARCHF4 | c.906T>C p.F302= | Silent (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823086 C>A | 5'Flank (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- IGHV1-69D | chr14:106762091 ins TCTCGCCA | 3'Flank (INS) | VAF 18/20 reads (90%) | called by mutect2, pindel, varscan2
